Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4KH, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4KH-01A (Primary Tumor).

DOB

Sex: F

Physician:

Collected

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

TOTAL THYROIDECTOMY, STITCH LEFT SUPERIOR LOBE: PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Left lobe *50% follicular variant per TSS.*

Multi-focal: Yes

Size = 2.1 cm, Largest focus, left lobe

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Lymph nodes:

No lymph nodes present

ICD-O-3

Path: Carcinoma, papillary and follicular 8340/3

Site: thyroid, NOS C73.9

10/4/12

CQCF: carcinoma, papillary, thyroid 8260/3

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY, STITCH LEFT SUPERIOR LOBE – Received is a total thyroidectomy (left lobe, 6.0 x 2.0 x 1.0; right lobe, 5.0 x 2.0 x 1.0 cm; isthmus, 2.5 x 1.2 cm; 30 grams in toto).

In the left upper lobe there is a (2.1 x 1.8 x 1.5 cm) solid cystic lesion with a pale-pink cut surface. Another small discrete nodule (0.8 x 0.5 x 0.5 cm) present immediately adjacent to this nodule with cut surface displaying possible papillations. The remainder of lower portion of the left lobe, isthmus, and the entire right lobe are grossly unremarkable. A portion of the tumor is submitted to the tissue bank.

SECTION CODE: A1-A3, left upper lobe nodule, entirely submitted; A4, left lobe uninvolved, representative; A5, isthmus uninvolved, representative; A6, right lobe, representative.

CLINICAL HISTORY

Papillary thyroid carcinoma

SNOMED CODES

T-B6000, M-83403, "Some tests reported here may have been developed and performance characteristics determined by these tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 155903e9-1617-4c33-b2cf-e5e861001fcd (TCGA-EL-A4KH.BDBCF63F-26B4-47E3-B609-F1B771544BE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).